Somatic mutation profile of tumor specimen TCGA-AK-3453-01A (aliquot TCGA-AK-3453-01A-01D-0966-08) from TCGA case TCGA-AK-3453, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 58.2 years (21,271 days).
Specimen TCGA-AK-3453-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26b881eb-7740-4b5b-b544-17ff06adc2a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3453-10A (Blood Derived Normal), aliquot TCGA-AK-3453-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96eedcd1-758b-48c7-a50c-6f8f1698a097

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 7, Frame Shift Del 1, Nonsense Mutation 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MESD | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1468421394; called by muse, mutect2, varscan2
- MRTFB | c.2530C>T p.P844S (on ENST00000571589 / NM_001365412.2; = p.P794S on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs767267381; called by muse, mutect2, varscan2
- OSBPL11 | c.1421G>T p.S474I | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as rs1176549004; called by muse, mutect2
- ARHGAP25 | c.559T>C p.F187L (on ENST00000409202 / NM_001007231.3; = p.F179L on NM_014882.3) | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2
- CYB5R4 | c.66del p.R23Vfs*6 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- ECSIT | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGD2 | c.977T>G p.V326G | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- MMP3 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- OSBPL1A | c.690C>G p.V230= | Splice Region (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- PLEKHA5 | c.53dup p.Y18* | Nonsense Mutation (INS) | VAF 5/33 reads (15%) | called by mutect2, pindel
- CA13 | c.222A>T p.T74= | Silent (SNP) | VAF 125/347 reads (36%) | called by muse, mutect2, varscan2
- COL8A1 | c.1404T>G p.G468= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- PAX3 | c.1425G>A p.K475= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1629G>A p.P543= | Silent (SNP) | VAF 11/329 reads (3%) | catalogued as rs782659113; called by muse, mutect2
- PEX6 | c.669G>T p.V223= | Silent (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- PGLYRP2 | c.1062G>A p.Q354= | Silent (SNP) | VAF 29/227 reads (13%) | called by muse, mutect2, varscan2
- TNFSF9 | c.570C>T p.S190= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs754327349; called by muse, mutect2, varscan2
- NXF5 | n.860G>T | RNA (SNP) | VAF 41/141 reads (29%) | called by muse, mutect2, varscan2
